CCDI case PBBVJB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/2c07886c-6530-4de6-90f0-9f86e38c052b

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Rhabdomyoma, NOS: ICD-O-3 morphology code: 8900/0; Tissue or organ of origin: Eyelid; Age at diagnosis: 6.8 years (2,480 days).

Biospecimens (3 samples)
- Sample 0DIDS2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIDSA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DIDST: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
